Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-6601, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-6601-01A (Primary Tumor).

PATIENT HISTORY:

The patient a [REDACTED]

PRE OP DIAGNOSIS: Colon cancer.

POST OP DIAGNOSIS: Same.

PROCEDURE: Sigmoid colectomy.

FINAL DIAGNOSIS:**PART 1: COLON, SIGMOID, PARTIAL COLECTOMY -**

Collection Date: [REDACTED]

- A. MODERATELY DIFFERENTIATED ADENOCARCINOMA, 6.0 CM.
- B. TUMOR INVADES THROUGH MUSCULARIS PROPRIA.
- C. TUMOR ARISES IN THE BACKGROUND OF A TUBULOVILLOUS ADENOMA.
- D. MARGINS OF RESECTION ARE FREE OF TUMOR.
- E. NO EVIDENCE OF ANGIOLYMPHATIC INVASION ARE IDENTIFIED.
- F. ELEVEN(11) LYMPH NODES ARE NEGATIVE FOR METASTATIC TUMOR.
- G. TNM PATHOLOGIC STAGE = pT3, N0, MX.
- H. TNM HISTOPATHOLOGIC GRADE = G2.
- I. DUKES' STAGE: B, ASTLER-COLLER STAGE: B2.
- J. SEPARATE SMALL TUBULAR ADENOMA, 0.2 CM.

PART 2: LYMPH NODE, PELVIC, EXCISION -

ONE(1) LYMPH NODE NEGATIVE FOR METASTATIC DISEASE.

SYNOPTIC - PRIMARY COLON AND RECTAL TUMORS

- A. Location: 5
- 1. Ileocecal Region
- 2. Ascending Colon
- 3. Transverse Colon
- 4. Descending Colon
- 5. Sigmoid Colon
- 6. Rectum
- B. Procedure: 1
- 1. Segmental Colectomy
- 2. Total Colectomy
- 3. Other
- C. Size of Tumor (maximum dimension): 6.0 cm
- D. Type: 1
- 1. Adenocarcinoma, NOS
- 2. Adenocarcinoma arising in a background of an adenoma.
- 3. Adenocarcinoma arising in a background of inflammatory bowel disease
- 4. Adenosquamous carcinoma
- 5. Carcinoid Tumor (Neuroendocrine Tumor)
- 6. Mucinous Adenocarcinoma
- 7. Signet ring cell type Adenocarcinoma
- 8. Neuroendocrine Carcinoma
- 9. Squamous Cell Carcinoma
- 10. Undifferentiated Carcinoma
- 11. Sarcoma
- 12. Smooth Muscle Tumor
- 13. Gastrointestinal stromal tumor
- 14. Lymphoma
- 15. Other
- E. Grade: 2
- 1. Well differentiated
- 2. Moderately differentiated
- 3. Poorly differentiated
- F. Extent of Infiltration: 4
- 1. Limited to the mucosa
- 2. Into submucosa
- 3. Involving muscularis propria
- 4. Infiltrating through muscularis propria into serosal adipose tissue
- 5. Involving adjacent organs/ pelvic wall
- G. Angiolymphatic Invasion: 2
- 1. Yes
- 2. No
- H. Surgical Margins Involved: 2
- 1. Yes
- 2. No
- I. Regional Lymph Node Involvement: 2
- 1. Yes
- 2. No
- J. If regional lymph nodes involved, Number positive/number examined: N/A / #.
- K. Extracapsular spread: N/A
- 1. Yes
- 2. No.
- L. Associated conditions: 3 / # / # / #
- 1. Ulcerative colitis.
- 2. Crohn's Disease.
- 3. History/ presence of adenomatous polyps.
- 4. Multiple polyposis syndromes.
- 5. Diverticulosis.
- M. TNM Stage: T 3 N 0 M X
- N. Dukes' Stage: 2
- 1. A (limited to mucosa and muscularis)
- 2. B (through muscularis into subserosa)
- 3. C (through subserosa and involving adjacent organ/pelvic wall/regional or distant lymph nodes)
- O. Astler - Coller Stage: 3
- 1. A (mucosa but not into muscularis propria)
- 2. B1 (muscularis propria but not through, LN negative)
- 3. B2 (through muscularis propria into subserosal fibroadipose tissue, LN negative)
- 4. C1 (limited to muscularis propria but not through serosa, LN positive)
- 5. C2 (invades serosal adipose tissue, LN positive)

Source: NCI Genomic Data Commons file d67fa203-7472-426a-977f-4ecb2368db6f (TCGA-AZ-6601.9F0F7A16-ACD5-46CC-9F83-B9F165380CA9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).